Somatic mutation profile of tumor specimen TCGA-HT-7684-01A (aliquot TCGA-HT-7684-01A-11D-2253-08) from TCGA case TCGA-HT-7684, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 58.5 years (21,352 days).
Specimen TCGA-HT-7684-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71dc7353-dc5d-41b5-917b-f71ade2484ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7684-10A (Blood Derived Normal), aliquot TCGA-HT-7684-10A-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5237ba8-0846-486d-986a-58dcbb0f6eb5

The open-access MAF lists 33 somatic variants for this specimen: 27 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 4, Frame Shift Del 2, Intron 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1463A>G p.D488G | Missense Mutation (SNP) | VAF 16/43 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66706118, COSV66708289; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 35/82 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ALG6 | c.536T>C p.L179P | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as COSV54764441; called by muse, mutect2, varscan2
- ANKAR | c.2488A>C p.N830H | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV55611414; called by muse, mutect2, varscan2
- C3 | c.1078A>G p.T360A | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as COSV55571343; called by muse, mutect2
- CCDC54 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as rs762728121, COSV53758412; called by muse, mutect2, varscan2
- DCLK1 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.397); catalogued as rs1566017267, COSV55180845; called by muse, mutect2, varscan2
- DLGAP4 | c.841G>T p.G281W | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.87); catalogued as COSV100210792, COSV59416526; called by muse, mutect2, varscan2
- EEF1A1 | c.82A>G p.I28V | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.044); catalogued as COSV58549314; called by muse, mutect2, varscan2
- EFTUD2 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as COSV53655180; called by muse, mutect2, varscan2
- HCCS | c.358T>C p.Y120H | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58238986; called by muse, mutect2, varscan2
- IQGAP1 | c.4273C>T p.Q1425* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | catalogued as COSV51583712; called by muse, mutect2, varscan2
- ISM2 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs369577194; called by muse, mutect2, varscan2
- KIF13B | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs1265643989, COSV73054236; called by muse, mutect2
- LY6G6F-LY6G6D | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 93/273 reads (34%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as COSV65419499; called by muse, mutect2, varscan2
- MAP4K3 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs866018265, COSV99811045; called by muse, varscan2
- MUSK | c.2124G>C p.Q708H | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51882980; called by muse, mutect2, varscan2
- NOL8 | c.1895A>G p.H632R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs973212142, COSV62634941; called by muse, mutect2, varscan2
- OR13D1 | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV59513738; called by muse, mutect2, varscan2
- OR14A16 | c.706T>C p.Y236H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV100713641; called by muse, mutect2
- PTGS1 | c.1645T>G p.F549V | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56291181; called by muse, mutect2, varscan2
- SLC9C1 | c.3191G>A p.R1064Q | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as rs377402243; called by muse, mutect2, varscan2
- SYNE2 | c.18683A>G p.N6228S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as rs1384940903, COSV59946509; called by muse, mutect2, varscan2
- TMTC1 | c.2603G>A p.R868H (on ENST00000539277 / NM_001193451.2; = p.R760H on NM_175861.3) | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs35279918; called by muse, mutect2, varscan2
- TRPC7 | c.2285T>C p.M762T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV61456521; called by muse, mutect2, varscan2
- KLHL28 | c.54del p.E19Nfs*7 | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | called by mutect2, pindel, varscan2
- USP32 | c.277_278del p.E93Rfs*8 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | called by mutect2, pindel, varscan2
- FOXG1 | c.549G>A p.P183= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs756638761, COSV57396154; called by muse, mutect2, varscan2
- LRP2 | c.9927G>A p.Q3309= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as COSV55548761; called by muse, mutect2, varscan2
- MS4A14 | c.912T>C p.F304= | Silent (SNP) | VAF 27/57 reads (47%) | catalogued as COSV55734133; called by muse, mutect2, varscan2
- TTYH2 | c.1389G>A p.Q463= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV53909693; called by muse, mutect2, varscan2
- DST | c.4297-4247C>T | Intron (SNP) | VAF 20/77 reads (26%) | catalogued as COSV99759573; called by muse, mutect2, varscan2
- SSPOP | n.3150C>G | RNA (SNP) | VAF 5/13 reads (38%) | catalogued as COSV50487098; called by muse, mutect2, varscan2
